Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOQ, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AAOQ-01A (Primary Tumor).

[page 1 of 2]
Name:

Sex:

Operative Procedure: ORCHIECTOMY

- Specimen Source: Right testicle
- Gross Exam Date:
- Physician:

Pager No.:

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

TESTIS: RADICAL ORCHIECTOMY

Specimen Laterality: Right

Tumor Focality: Multifocal (two almost contiguous nodules)

Tumor Size: 2.0 x 1.5 x 0.5 cm and 3.0 x 2.0 x 2.0 cm

Macroscopic Extent of Tumor: Tumor approaches tunica vaginalis

Histologic Type: Seminoma with syncytiotrophoblasts

Margins: Spermatic cord margin free of tumor

Microscopic Tumor Extension: Tumor extends through the tunica vaginalis and albuginea.

Lymph-Vascular Invasion: Not identified

Pathologic Staging: (pTNX)

Primary Tumor: (pT2)

Regional Lymph Nodes (pN): N/A

Distant Metastasis (pM): N/A

ICD-O-3

Seminoma NOS 9061/3

Site @ Testis NOS C62.9

4/3/21/4

Comments: There is testicular atrophy of uninvolved testis and intratubular germ cell neoplasia.

Ancillary studies: The seminoma is CD117 positive and CD30 and HGH negative. The syncytiotrophoblasts are HGH and AE1/AE3 positive. These findings support the above diagnosis.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

[page 2 of 2]
Name:

Sex:

Operative Procedure: ORCHIECTOMY

CQ - Specimen Source: Right testicle

CQ - Gross Exam Date:

CQ - Physician:

Pager No.:

GROSS DESCRIPTION:

Specimen was received in one part, fixed in formalin, labeled with the patient's name, , and "right testicle." The specimen consists of a testicle weighing 46.7 g. The testes measures 3.0 x 3.0 x 2.0 cm. The spermatic cord measures 8.5 cm in length x 1.5 cm in diameter, and the epididymis measures 3.0 x 1.5 x 0.5 cm. The specimen is inked black prior to bivalving the specimen. Sectioning of the specimen reveals two tan-pink solid tumor masses. The first is at the upper pole of the testes and measures 2.0 x 1.5 x 1.5 cm. The second is in the lower pole of the testis and measures 3.0 x 2.0 x 2.0 cm. Both tumors approach the tunica albuginea within less than 0.1 cm. There is a fragment of normal appearing testes measuring 1.5 x 1.2 cm. The remainder of the testis is occupied by the tumor mass.

Summary of cassettes:

1. Spermatic cord resection margin.
2. Spermatic cord midportion.
3. Spermatic cord peritesticular portions.
- 4-6. Nodule in the upper pole.
7. Upper tumor nodule with tunica albuginea and tunica vaginalis.
8. Upper tumor nodule with uninvolved testicular tissue and tunica albuginea.
9. Lower tumor nodule with tunica albuginea, tunica vaginalis, and vas deferens.
10. Uninvolved testicular tissue. R10.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION
---	-----------------------------

SURGICAL PATHOLOGY TISSUE REPORT

PAGE 4

Source: NCI Genomic Data Commons file 1ab77a08-1eb8-40b4-85d4-49dc737ef355 (TCGA-XE-AAOQ-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).